CPTAC case C3L-09775 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ad24d74d-bb4a-47d8-abb2-23a686c5a9f0

Demographics
Sex at birth: male; Race: white; Year of birth: 1957; Vital status: Alive; Country of birth: Romania.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 65.1 years (23,768 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic stage: Stage IA; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 703 days (1.9 years); Progression or recurrence: no; Days to last follow up: 703 days (1.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 24.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 52 days; Days to treatment end: 80 days; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 333.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09775-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 22 days; Initial weight: 57 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09775-21: Section location: Body; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample C3L-09775-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 22 days; Initial weight: 55 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09775-22: Section location: Body; Percent tumor nuclei: 40; Percent necrosis: 0.
- Sample C3L-09775-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 22 days; Initial weight: 57 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09775-23: Section location: Body; Percent tumor nuclei: 35; Percent necrosis: 0.
- Sample C3L-09775-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 22 days; Method of sample procurement: Blood Draw.
